FM case AD4160 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach.
https://portal.gdc.cancer.gov/cases/4c378f20-5552-4c34-9ced-31083d2d89e8

Male, 62.5 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the stomach. Tumor nuclei on the sequenced sample's slide: 55% (pathologist estimate recorded by GDC). Sample type: Tumor.
